Somatic mutation profile of tumor specimen CDDP-ACK4-TTP1-A (aliquot CDDP-ACK4-TTP1-A-2-0-D-A572-36) from CDDP_EAGLE case CDDP-ACK4, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 71 years.
Specimen CDDP-ACK4-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ef8b106-8053-488c-bf9a-5858baaeb44e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ACK4-NB1-A (Blood Derived Normal), aliquot CDDP-ACK4-NB1-A-1-0-D-A572-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e50089a-7250-4ee1-ac19-87cb9c70d09a

The open-access MAF lists 40 somatic variants for this specimen: 24 protein-altering or splice-affecting, 3 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Intron 10, Silent 3, 3'UTR 2, Frame Shift Ins 2, RNA 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BSN | c.3640G>T p.G1214C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV56528681; called by mutect2, varscan2
- FAM47A | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.8); catalogued as rs772335767, COSV60495726, COSV99080509; called by mutect2, varscan2
- GOSR2 | c.674T>C p.I225T | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs1419639632; called by muse, mutect2
- PLCB1 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs1471447131, COSV62056067; called by muse, mutect2
- POU4F2 | c.598C>A p.L200M | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.205); catalogued as COSV55584788; called by muse, varscan2
- RAPGEF5 | c.833A>G p.Y278C (on ENST00000401957 / NM_001367602.2; = p.Y581C on NM_012294.5) | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV59788804; called by muse, mutect2
- SETBP1 | c.3056G>A p.R1019H | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs140544874; called by muse, mutect2, varscan2
- SLC22A7 | c.1183T>A p.L395M (on ENST00000372585 / NM_153320.2; = p.L393M on NM_006672.3) | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as COSV99240441; called by muse, mutect2
- SLC2A9 | c.1472G>A p.G491D | Missense Mutation (SNP) | VAF 42/457 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as COSV53322067; called by muse, mutect2
- ACVR1B | c.1185dup p.D396* | Frame Shift Ins (INS) | VAF 15/77 reads (19%) | called by mutect2, pindel, varscan2
- CMTR2 | c.1557del p.N520Mfs*8 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | called by mutect2, pindel, varscan2
- CSNK1G2 | c.649C>G p.R217G | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ERBB4 | c.3056C>T p.A1019V | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- FAM90A1 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 33/257 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- MAPK8IP3 | c.362A>C p.E121A | Missense Mutation (SNP) | VAF 48/296 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- NOVA2 | c.355C>T p.L119F | Missense Mutation (SNP) | VAF 21/234 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2
- NSL1 | c.286C>A p.Q96K | Missense Mutation (SNP) | VAF 36/340 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- OR2AT4 | c.841_842insC p.V281Afs*37 | Frame Shift Ins (INS) | VAF 6/64 reads (9%) | called by mutect2, varscan2
- RYR3 | c.8813G>A p.R2938K (on ENST00000389232; = p.R2939K on NM_001036.6) | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.98); called by muse, mutect2
- SCN2A | c.2485T>A p.F829I | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TAB3 | c.652C>T p.Q218* | Nonsense Mutation (SNP) | VAF 37/236 reads (16%) | called by muse, mutect2, varscan2
- TGFBR3 | c.301G>C p.V101L | Missense Mutation (SNP) | VAF 28/384 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); called by muse, mutect2
- TRANK1 | c.662G>T p.R221L | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- UBFD1 | c.923A>G p.Y308C | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- BMP15 | c.666T>C p.H222= | Silent (SNP) | VAF 13/252 reads (5%) | catalogued as rs1408453614; called by muse, mutect2
- DENND3 | c.1797G>A p.T599= | Silent (SNP) | VAF 35/122 reads (29%) | catalogued as rs762525324, COSV52805547, COSV99371658; called by muse, mutect2, varscan2
- TSEN34 | c.679C>T p.L227= | Silent (SNP) | VAF 28/268 reads (10%) | called by muse, mutect2, varscan2
- AC104472.1 | n.380A>G | RNA (SNP) | VAF 7/44 reads (16%) | catalogued as rs1468214061; called by muse, varscan2
- AK7 | c.2134-276T>C | Intron (SNP) | VAF 11/99 reads (11%) | catalogued as rs1334656460; called by muse, varscan2
- C1R | c.44+10T>C | Intron (SNP) | VAF 54/160 reads (34%) | called by muse, mutect2, varscan2
- C4BPB | c.410-1152T>A | Intron (SNP) | VAF 11/445 reads (2%) | called by muse*, mutect2
- CELF2 | c.53+12677del | Intron (DEL) | VAF 31/209 reads (15%) | called by mutect2, pindel, varscan2
- DDX19A | c.57+849T>C | Intron (SNP) | VAF 5/40 reads (13%) | called by mutect2, varscan2
- EIF2A | c.99-726C>G | Intron (SNP) | VAF 16/166 reads (10%) | catalogued as rs1206483162, COSV56409313; called by muse, mutect2
- FAM161A | c.*555T>C | 3'UTR (SNP) | VAF 21/180 reads (12%) | catalogued as rs1195163165; called by muse, varscan2
- NFS1 | c.409-1708T>G | Intron (SNP) | VAF 12/124 reads (10%) | catalogued as rs78508372; called by mutect2, varscan2
- NOP2 | c.475-227T>C | Intron (SNP) | VAF 16/251 reads (6%) | catalogued as rs1246954241, COSV59110776; called by muse, mutect2
- RHOA | c.409-654T>A | Intron (SNP) | VAF 9/43 reads (21%) | catalogued as rs1201900683; called by muse, varscan2
- TMIGD2 | c.*99G>C | 3'UTR (SNP) | VAF 20/192 reads (10%) | called by muse, varscan2
- TYK2 | c.194-1368T>C | Intron (SNP) | VAF 16/166 reads (10%) | catalogued as rs1386730107; called by muse, mutect2
